Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6158, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6158-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
[REDACTED] male with adenocarcinoma T2NO lesion in distal rectum.

Specimens Submitted:
1: Rectum; transanal excision:
2: SP: Additional meso-rectal tissue

DIAGNOSIS:
1. Rectum; transanal excision::
Tumor Type:
Adenocarcinoma
Histologic Grade:
Moderately differentiated
Tumor Location:
Rectum
Tumor Size:
3.6 x 2.2 x 0.6 cm
Tumor Budding:
Absent
Increased Tumor Infiltrating Lymphocytes:
Absent
Precursor Lesions:
Not identified
Deepest Tumor Invasion:
Muscularis propria
Lymphovascular Invasion:
Identified
Large Venous Invasion:
Not Identified
Perineural Invasion:
Identified
Surgical Margins:
Free of tumor
0.2cm from distal resection margin
0.2 cm between deepest tumor portion and deep (radial soft tissue)
margin
0.2 cm from lateral margins and 0.5 cm from proximal margin
Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified
Non-Neoplastic Bowel:

** Continued on next page **

[page 2 of 3]
Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 1

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC

pT2 (Tumor invades muscularis propria)

2. RECTUM AND MESORECTAL TISSUE; EXCISION:
- BENIGN RECTAL TISSUE AND FIBROADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled "Posterior transanal excision of rectal tumor" and consists of an oriented portion of rectal mucosa measuring 5.8 cm (distal to proximal) x 3.7 cm (left to right) x 0.3 cm. The mucosa displays an red tan papillary lesion measuring 3.6 x 2.2 cm located 0.2 cm -- right, 0.5 cm -- proximal, 0.1 cm -- proximal, 0.2 cm -- left from the mucosal margin. Gross photographs are taken. TPS has been previously taken by the attending. The left half is inked black, the right half is inked blue. Upon sectioning the lesion has yellow papillary extension to a depth of 0.6 cm. Perpendicular sections of the distal and proximal margins are submitted. The remaining specimen is serially sectioned from distal to proximal in its entirety.

Summary of sections:

DM-- distal margin (perpendicular)

SS - sequential sections from distal to proximal

PM-- proximal margin (perpendicular)

2.) The specimen is received in formalin, labeled "Additional mesorectal tissue" and consists of a 3.5 x 2.4 x 0.9 cm aggregate of multiple, irregular, fibrofatty tissue fragments, some with partially overlying, focally congested, tan-pink mucosa. The specimen is entirely submitted.

** Continued on next page **

[page 3 of 3]
[REDACTED]

Summary of sections:
MR -- mesorectal tissue

Summary of Sections:
Part 1: Rectum; transanal excision:

Block	Sect. Site	PCs
5	DM	5
5	PM	5
8	SS	8

Part 2: SP: Additional meso-rectal tissue

Block	Sect. Site	PCs
4	MR	10

** End of Report **

Source: NCI Genomic Data Commons file 7d7a84d0-ff6d-49c1-993b-247aecf2e5f0 (TCGA-DC-6158.38C33CC8-7EEC-46F7-983E-3C5AB2A4AEEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).